Surgical pathology report (de-identified scan), TCGA case TCGA-YD-A9TB, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Spectrum Health, specimen TCGA-YD-A9TB-06A (Metastatic).

[page 1 of 2]
Research Gross Description

-year-old female with metastatic melanoma to the uterus

Research Dx

Metastatic melanoma to the uterus

A. Uterus bilateral tubes and ovaries, laparoscopic assisted vaginal hysterectomy and bilateral salpingo-oophorectomy:

Metastatic melanoma, 2.3 cm in greatest dimension, noted in the right superior anterior endometrium.

No lymphatic vascular invasion is noted.

Benign ectocervix and endocervix with tunnel cluster and nabothian cysts.

Proliferative endometrium.

Benign leiomyomas, intramural (x3) up to 1 cm in greatest dimension.

Right ovary with benign serous cyst, and follicular cysts, one cyst with hemorrhagic rim.

Left ovary with hemorrhagic corpus luteal cyst.

Bilateral benign fallopian tubes with congestion.

Margins free of tumor.

Research QC

Tumor T1:

95% tumor nuclei (consistent with melanoma)

0% necrosis

5% normal (endomyometrium)

ICD-O-3

Melanoma NOS 8726/3

Site Endometrium C54.1

YD 11/17/14

Research Specimen

-

Specimen Process Time

Blood draw time:

Plasma frozen time:

Serum frozen time:

Buffy coat frozen time:

Tissue:

Cold ischemia start time:

Formalin fixation start time:

Frozen start time:

Total cold ischemia time: 55 minutes

Formalin fixation stop time:

Total formalin fixation time: A total fixation time is 6 hours and 45 minutes

Specimen Weight

Normal-myometrium

1. 228 mg

2. 155 mg

3. 359 mg

[page 2 of 2]
Tumor-metastatic melanoma to anterior endometrium

1. 194 mg

Specimen Size

Plasma x 3

Serum x 2

Buffy coat x 1

Cryovials x 4

Normal x 3

Metastatic x 1

FFPE x 4

Normal x 3

Metastatic x 1

Study

Patient Consent

Yes

Source: NCI Genomic Data Commons file a6b95d28-fb50-4b54-99a1-bb815eb971dd (TCGA-YD-A9TB.9985BBA4-AD5A-45C5-B7A8-9641B5A85B55.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).